Somatic mutation profile of tumor specimen 0DRELF from CCDI case PBCFVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 12.2 years (4,472 days).
Specimen 0DRELF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a7896b7-178f-409c-9c0a-7f8ed47e309f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRELD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bd2b733-bc3a-45b3-8128-7f36c08799f2

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 22/620 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1300143811; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 64/1418 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DPP10 | c.1404T>A p.C468* | Nonsense Mutation (SNP) | VAF 41/1432 reads (3%) | called by muse, mutect2
- PLA2R1 | c.1499T>A p.I500N | Missense Mutation (SNP) | VAF 36/920 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/1110 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- PLA2R1 | c.1500T>A p.I500= | Silent (SNP) | VAF 34/919 reads (4%) | called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
